CCDI case PBBVDY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/268feef1-e002-4643-8e2f-e470f3ec5c7c

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 7.2 years (2,633 days).

Biospecimens (3 samples)
- Sample 0DI6KH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DI6KO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI6KZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
